Somatic mutation profile of tumor specimen TCGA-XV-A9VZ-01A (aliquot TCGA-XV-A9VZ-01A-11D-A38G-08) from TCGA case TCGA-XV-A9VZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-XV-A9VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2045d62d-010b-4f44-9fd0-eb2a4e2e38f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-A9VZ-10A (Blood Derived Normal), aliquot TCGA-XV-A9VZ-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187ccbc7-0d31-4bea-bb49-6da15576a400

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 45/94 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- AP1B1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757585860, COSV100434487; called by muse, mutect2, varscan2
- CCDC88B | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.046); catalogued as COSV100105243; called by muse, mutect2, varscan2
- FBXO34 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100571893; called by muse, mutect2, varscan2
- HAUS1 | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV99959413; called by muse, mutect2, varscan2
- MYH9 | c.5747C>T p.S1916F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV99338417; called by muse, varscan2
- NOL4 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774633323, COSV52344423, COSV52349065; called by muse, mutect2, varscan2
- PAK2 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100506017; called by muse, varscan2
- PRRG3 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.916); catalogued as COSV100948584; called by muse, mutect2, varscan2
- UBXN1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99583188; called by muse, mutect2
- GAS2L2 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- ZNF276 | c.648del p.Q217Rfs*136 (on ENST00000443381 / NM_001113525.2; = p.Q142Rfs*136 on NM_152287.4) | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- OSBP2 | c.1896G>A p.A632= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs764591046, COSV100212854; called by muse, mutect2, varscan2
- SLCO3A1 | c.1821C>T p.F607= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs750091814, COSV100575170; called by muse, mutect2, varscan2
